FM case AD1217 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Trachea.
https://portal.gdc.cancer.gov/cases/6d0b7e17-c36a-4550-b719-06e8539a57c6

Female, 59.1 years: Adenoid cystic carcinoma (ICD-O-3 8200/3) of the trachea; primary biopsied or resected from the trachea. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
